Gene-level copy-number profile of tumor specimen C3N-03072-01 (profiled together with C3N-03072-02) from CPTAC case C3N-03072, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.0 years (22,994 days).
Specimen C3N-03072-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 635914b3-6cdc-415c-82f0-f88068626608.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03072-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/11c7e624-5a7d-4a10-a17e-44c6cf123c9c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 586; copy number 1: 219; copy number 2: 19,357; copy number 3: 14,713; copy number 4: 17,283; copy number 5: 4,904; copy number 6: 330; copy number 7: 627; copy number 8: 381; copy number 9: 255; copy number 10: 150; copy number 11: 86; copy number 12: 3; copy number 17: 1; copy number 18: 1; copy number 32: 2; copy number 43: 2.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,424,645–8,807,051, 7 genes (within-gene range 0–2): RERE-AS1, AL096855.1, AL096855.2, RPL7P11, Y_RNA, AL357552.1, AL357552.2.
- chr1:43,933,320–43,937,240, 1 gene: ARTN.
- chr1:115,976,513–116,070,054, 2 genes: SLC22A15, AL365318.1.
- chr2:218,781,749–218,815,293, 2 genes: CYP27A1, AC009974.2.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:29,887,294–29,934,286, 8 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr8:7,768,977–7,795,870, 3 genes: FAM90A10P, PRR23D2, PRR23D3P.
- chr9:18,360,597–18,362,220, 1 gene: AL442638.1.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–4): AL772307.1.
- chr9:40,105,822–40,266,845, 5 genes (within-gene range 0–5): AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P.
- chr9:40,233,923–40,234,029, 1 gene: RNU6-1269P.
- chr10:77,730,766–77,926,755, 7 genes (within-gene range 0–2): AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1.
- chr10:87,863,625–87,971,930, 3 genes: PTEN, AC063965.2, RPL11P3.
- chr14:67,727,374–67,816,590, 4 genes (within-gene range 0–2): ZFYVE26, AL049779.3, RN7SL213P, AL049779.2.
- chr14:68,113,706–68,149,908, 3 genes (within-gene range 0–2): AL133370.2, AL133370.1, RN7SL706P.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr16:72,278,268–72,278,568, 1 gene: AC009075.2.
- chr16:79,585,843–79,600,737, 1 gene: MAF.
- chr17:4,143,168–4,268,430, 6 genes: CYB5D2, ANKFY1, AC087292.1, Y_RNA, RYKP1, AC087742.1.
- chr17:4,301,372–4,302,698, 1 gene (within-gene range 0–2): MFSD1P1.
- chr20:47,071,865–47,072,236, 1 gene (within-gene range 0–2): AL121776.1.
- chr21:44,107,373–44,210,114, 6 genes: PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 500 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:183,083,405–183,495,501, 5 genes, copy number 18–43 (within-gene range 4–43): AC064871.2, NUP35, AC021851.1, AC021851.2, LIN28AP1.
- chr3:93,843,764–94,938,024, 13 genes, copy number 11: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1.
- chr3:141,051,347–141,367,753, 7 genes, copy number 10 (within-gene range 6–11): SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2.
- chr3:142,949,164–153,377,562, 161 genes, copy number 10–11 (broad region; genes not listed).
- chr3:158,105,855–160,225,299, 32 genes, copy number 11 (within-gene range 8–11): RSRC1, AC074276.1, AC074276.2, AC106707.2, AC106707.1, MLF1, MTAPP1, AC025033.1, GFM1, LXN, AC080013.3, RARRES1, MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79, AC092999.1, IQCJ-SCHIP1, IQCJ, MIR3919, AC063955.1, AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1, IL12A-AS1, IL12A, LINC01100, BRD7P2.
- chr3:188,947,214–189,325,304, 1 gene, copy number 10 (within-gene range 7–10): TPRG1.
- chr3:189,238,686–198,123,232, 206 genes, copy number 9–10 (broad region; genes not listed).
- chr4:49,238,032–49,246,915, 3 genes, copy number 12: AC118282.1, MTCO3P39, MTND3P22.
- chr4:60,922,619–60,922,684, 1 gene, copy number 11: MIR548AG1.
- chr8:49,086,301–49,352,844, 3 genes, copy number 9: AC044893.1, RN7SKP294, RFPL4AP7.
- chr9:64,621,560–64,637,586, 1 gene, copy number 11: AQP7P2.
- chr9:64,765,054–64,765,535, 1 gene, copy number 17: IGKV1OR-2.
- chr11:22,010,402–22,170,001, 2 genes, copy number 9: AC116534.1, AC107882.1.
- chr14:101,964,573–102,056,443, 1 gene, copy number 9 (within-gene range 4–9): DYNC1H1.
- chr14:102,036,315–102,066,228, 1 gene, copy number 9: AL118558.1.
- chr20:31,257,664–32,608,893, 62 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 218. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
